Surgical pathology report (de-identified scan), TCGA case TCGA-VV-A86M, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site  John Wayne Cancer Center, specimen TCGA-VV-A86M-01A (Primary Tumor).

[page 1 of 3]
Coll:
Recd:

ICB-0-3
Astrocytoma, grade III 9401/3
Site: CQCF - brain, supratentorial, NOS C71.0
Path - brain, NOS C71.9 hr 9/17/14

GROSS DESCRIPTION

1. Labeled "left frontal tumor": The specimen consists of a 1.0 x 0.7 x 0.2 cm pale tan glistening delicate piece of soft tissue. Touch preps are prepared. Half of the specimen is submitted for frozen section in 1FSA. The remainder is submitted in 1B.

INTRAOPERATIVE CONSULTATION (FROZEN SECTION):
- Glioma, favor high grade glioma.

Intraoperative consultation reported to

2. Labeled "left frontal brain tumor": The specimen consists of a 2.1 x 1.3 x 0.2 cm ovoid portion of pale pink glistening delicate soft tissue. Touch preps are prepared. The specimen is submitted entirely for frozen section in 2FSA-2B.

INTRAOPERATIVE CONSULTATION (FROZEN SECTION 1FSA):
- Consistent with glioma, favor high grade.

Frozen section diagnosis reported to

INTRAOPERATIVE CONSULTATION (FROZEN SECTION 1FSB):
- Consistent with glioma, favor high grade.

Frozen section diagnosis reported to

INTRAOPERATIVE CONSULTATION (WITH CYTOLOGY EVALUATION):
- Consistent with glioma, favor high grade.

Intraoperative consultation reported to

3. Labeled "left frontal lobe tumor": The specimen consists of a 2.1 x 1.8 x 1.0 cm aggregate of pale pink red glistening delicate soft tissue fragments. The majority of the specimen is submitted for research per surgeon request and the remainder is submitted in 3A.

4. Labeled "left temporal lobe tumor": The specimen consists of a 0.4 x 0.4 x 0.2 cm pink red glistening delicate piece of soft tissue. Touch preps are prepared. The specimen is submitted entirely for frozen section in 4FSA.

INTRAOPERATIVE CONSULTATION (FROZEN SECTION):
- High grade glioma.

Frozen section diagnosis reported to

INTRAOPERATIVE CONSULTATION (WITH CYTOLOGY EVALUATION):
- High grade glioma.

Intraoperative consultation reported to

5. Labeled "left temporal lobe tumor": The specimen consists of a 2.2 x 1.1 x
Page 1

[page 2 of 3]
0.3 cm aggregate of pink red glistening delicate soft tissue fragments. The majority of the specimen is submitted for research per surgeon request and the remainder is submitted in 5A and a tiny portion is submitted in 5A.

6. Labeled "deep left frontal lobe tumor": The specimen consists of a 2.2 x 1.1 x 0.5 cm pink red ovoid glistening piece of delicate soft tissue. Touch preps are prepared and approximately one-third of the specimen is submitted for frozen section in 6FSA. The remainder is submitted in 6B.

INTRAOPERATIVE CONSULTATION (FROZEN SECTION):

- Glioma; within spectrum of grade II to III.
- Final grade deferred to permanents.

Frozen section diagnosis reported to

INTRAOPERATIVE CONSULTATION (WITH CYTOLOGY EVALUATION):

- Glioma; within spectrum of grade II to III.
- Final grade deferred to permanents.

Intraoperative consultation reported to

7. Labeled "left frontal lobe tumor": The specimen consists of a 7.1 x 3.5 x 0.6 cm aggregate of pink red to gray white irregular fragments of glistening soft tissue fragments. Sectioning reveals a markedly soft and mucoid soft surface. The specimen is submitted entirely in 7A-D.

8. Labeled "left temporal lobe tumor": The specimen consists of a 1.5 x 1.2 x 0.4 cm pink red glistening delicate piece of soft tissue. The specimen is wrapped, submitted entirely in 8A.

9. Labeled "deep left frontal lobe tumor": The specimen consists of a 4.0 x 3.8 x 1.5 cm aggregate of pink red to gray white irregular glistening delicate soft tissue fragments. Sectioning reveals a soft cut surface. Representative sections are submitted in 9A-B.

Microscopic H&E stained sections are prepared and interpreted.

COMMENT

The clinical history of recently excised low grade astrocytoma (WHO Grade II) is noted. Indeed, surgical residua of this procedure are noted in Specimen #7. Multiple biopsies from the frontal lobe, and tumor immediately adjacent to the surgical cavity (specimen #7) shows astrocytoma with marked cytologic atypia, hypercellularity and scattered mitotic figures. The degree of atypia attains that of high grade astrocytoma, WHO Grade III. The diagnostic features of a glioblastoma multiforme, i.e. necrosis, endothelial proliferation, are not identified. Diffusely involving the majority of the resected tissue in specimens #7, #8 and #9 is astrocytoma with grade II features: moderate hypercellularity, inconspicuous mitotic figures, and mild to moderate nuclear atypia. Overall, we estimate that approximately 20% of the tumor resected shows grade III features and approximately 80% shows grade II features. This is of course a somewhat arbitrary estimate, as the differentiating criteria (hypercellularity, atypia) exist on a spectrum and are not clearly delineated.

DIAGNOSIS

1. BRAIN, LEFT FRONTAL LOBE, BIOPSY:
- HIGH GRADE ASTROCYTOMA (SEE SPECIMEN #7).

[page 3 of 3]
2. BRAIN, LEFT FRONTAL LOBE, BIOPSY:
- HIGH GRADE ASTROCYTOMA (SEE SPECIMEN #7).
3. BRAIN, LEFT FRONTAL LOBE, BIOPSY:
- HIGH GRADE ASTROCYTOMA (SEE SPECIMEN #7).
4. BRAIN, LEFT TEMPORAL LOBE, BIOPSY:
- HIGH GRADE ASTROCYTOMA (SEE SPECIMEN #7).
5. BRAIN, LEFT TEMPORAL LOBE, BIOPSY:
- HIGH GRADE ASTROCYTOMA (SEE SPECIMEN #7).
6. BRAIN, DEEP LEFT FRONTAL LOBE, EXCISION:
- ASTROCYTOMA, LOW GRADE, WHO GRADE II, 2.2 CM IN GREATEST DIMENSION.
- SEE COMMENT AND SPECIMEN #7.
7. BRAIN, LEFT FRONTAL LOBE, EXCISION:
- ASTROCYTOMA, HIGH GRADE, WHO GRADE III; ARISING IN THE BACKGROUND OF
DIFFUSE ASTROCYTOMA (I.E. LOW GRADE ASTROCYTOMA) WHO GRADE II; 7.1 CM
IN GREATEST AGGREGATE DIMENSION.
- CHANGES CONSISTENT WITH SURGICAL CAVITY IDENTIFIED.
- SEE COMMENT.
8. BRAIN, LEFT TEMPORAL LOBE, EXCISION:
- HIGH GRADE ASTROCYTOMA, WHO GRADE III; ARISING IN THE BACKGROUND OF
DIFFUSE (LOW GRADE) ASTROCYTOMA, WHO GRADE II, 1.5 CM GREATEST
AGGREGATE DIMENSION.
9. BRAIN, LEFT FRONTAL LOBE DEEP, EXCISION:
- HIGH GRADE ASTROCYTOMA, WHO GRADE III; ARISING IN THE BACKGROUND OF
DIFFUSE (LOW GRADE) ASTROCYTOMA, WHO GRADE II, 4.0 CM GREATEST
AGGREGATE DIMENSION.

CENTRAL NERVOUS SYSTEM TUMOR SYNOPTIC REPORT

TUMOR SITE:	Frontal and temporal lobes
LATERALITY:	Left
HISTOLOGIC TYPE:	Astrocytoma
HISTOLOGIC GRADE (WHO):	grade III, arising within background of grade II
ANCILLARY STUDIES:	N/A

Signed Electronically signed by:

** END OF REPORT **

Diagnosis Discrepancy	?	✓
Primary Tumor Site Discrepancy	?	✓
WHO Grade Discrepancy	?	✓
Prior Malignancy History	?	✓
Qual/Synchronous Primary Notes	?	✓

Source: NCI Genomic Data Commons file 072d6055-546a-47dd-adf8-a2fd4eb803db (TCGA-VV-A86M.866E82BA-87CA-408F-A0E5-13ECE3AC8059.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).